Somatic mutation profile of tumor specimen HCM-CSHL-0853-C56-07B (aliquot HCM-CSHL-0853-C56-07B-11D-A881-36) from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-07B: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de281886-9881-4ebd-ab5b-ac423a84611f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6008efc-9e1a-4d86-8e19-99a57858f81c

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, 5'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 168/383 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 258/1348 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CACNA1D | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 64/501 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as rs1025180323, COSV55445495; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 189/543 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- FAT1 | c.8558G>A p.S2853N | Missense Mutation (SNP) | VAF 105/557 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs771064453, COSV71675216; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 123/454 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- IGSF3 | c.2326G>A p.D776N (on ENST00000369486 / NM_001007237.3; = p.D796N on NM_001542.4) | Missense Mutation (SNP) | VAF 76/712 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768697516; called by muse, mutect2, varscan2
- MAP2K5 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs760337605, COSV51614512; called by muse, varscan2
- MRGPRG | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 31/1076 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs1180057997; called by muse, mutect2
- OR5R1 | c.567C>G p.C189W | Missense Mutation (SNP) | VAF 24/876 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100393585; called by muse, mutect2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/454 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- TMEM175 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 227/723 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs577438263, COSV53279397; called by muse, varscan2
- UNC5D | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 170/805 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs568619133; called by muse, mutect2, varscan2
- ZNF461 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 24/662 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64454997; called by muse, mutect2
- BEST2 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 166/565 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CETP | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 83/505 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CKMT1A | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 19/675 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2
- CSPG4 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 200/981 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CSPG4 | c.2563G>C p.G855R | Missense Mutation (SNP) | VAF 197/980 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DNER | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 81/566 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- FAM214B | c.1063T>G p.S355A | Missense Mutation (SNP) | VAF 52/501 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBN3 | c.6535T>A p.F2179I | Missense Mutation (SNP) | VAF 69/409 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 13/453 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- GOLGA6L6 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 36/888 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GYS1 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 156/329 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NDUFS4 | c.422dup p.N141Kfs*6 | Frame Shift Ins (INS) | VAF 79/282 reads (28%) | called by mutect2, varscan2
- NRXN1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 31/642 reads (5%) | called by muse, mutect2
- ORAI1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 24/701 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- PHLDA2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 56/1066 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 239/635 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SCN3A | c.3251T>A p.V1084E | Missense Mutation (SNP) | VAF 38/581 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.071); called by muse, mutect2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 134/574 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TNKS1BP1 | c.2673_2682del p.D892Vfs*64 | Frame Shift Del (DEL) | VAF 141/744 reads (19%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 83/606 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM20 | c.507A>C p.P169= | Silent (SNP) | VAF 27/656 reads (4%) | called by muse, mutect2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 99/274 reads (36%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1146G>A p.K382= | Silent (SNP) | VAF 100/973 reads (10%) | catalogued as rs1047612129; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 62/380 reads (16%) | called by muse, mutect2, varscan2
- BACE1 | c.534C>T p.G178= | Silent (SNP) | VAF 125/718 reads (17%) | catalogued as rs755703640; called by muse, mutect2, varscan2
- CATSPER2 | c.711C>T p.A237= | Silent (SNP) | VAF 68/317 reads (21%) | catalogued as COSV58661491; called by muse, mutect2, varscan2
- CSMD1 | c.1737C>T p.P579= (on ENST00000520002; = p.P578= on NM_033225.6) | Silent (SNP) | VAF 77/369 reads (21%) | catalogued as rs906685310; called by muse, mutect2, varscan2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 312/970 reads (32%) | called by muse, mutect2, varscan2
- PDCD11 | c.1410G>A p.V470= | Silent (SNP) | VAF 31/627 reads (5%) | called by muse, mutect2
- PXDN | c.480C>T p.L160= | Silent (SNP) | VAF 72/517 reads (14%) | catalogued as rs1320356614; called by muse, mutect2, varscan2
- RBM25 | c.432C>G p.L144= | Silent (SNP) | VAF 22/688 reads (3%) | called by muse, mutect2
- SERINC2 | c.792C>G p.P264= (on ENST00000373709 / NM_178865.5; = p.P268= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/656 reads (4%) | called by muse, mutect2
- SIGIRR | c.747G>A p.L249= | Silent (SNP) | VAF 40/788 reads (5%) | called by muse, mutect2
- SKP2 | c.210G>T p.L70= | Silent (SNP) | VAF 30/891 reads (3%) | called by muse, mutect2
- WDR35 | c.2011C>T p.L671= (on ENST00000345530 / NM_001006657.2; = p.L660= on NM_020779.4) | Silent (SNP) | VAF 22/702 reads (3%) | called by muse, mutect2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 238/934 reads (25%) | called by mutect2, pindel, varscan2
